MMRF case MMRF_2602 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8b86cd08-9096-4ba6-9167-e54a77e356b0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.9 years (18,956 days); ISS stage: III; Days to last known disease status: 1 day; Days to last follow up: 1 day.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Hemoglobin 5.09 mmol/L.
- Albumin 30 g/L.
- Serum Free Immunoglobulin Light Chain, Lambda 917 mg/dL.
- Immunoglobulin A 3.39 g/L.
- Leukocytes 11.8 ×10⁹/L.
- Blood Urea Nitrogen 21.4 mmol/L.
- C-Reactive Protein 0.032 mg/dL.
- Immunoglobulin M 0.18 g/L.
- Platelets 136 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL.
- Absolute Neutrophil 9.26 ×10⁹/L.
- Total Protein 4.92 g/dL.
- Creatinine 707 µmol/L.
- Glucose 4.51 mmol/L.
- Immunoglobulin G 6.06 g/L.
- Beta 2 Microglobulin 14.1 µg/mL.
- Calcium 2 mmol/L.

Other clinical attributes
- Day 1: Weight: 96 kg; Height: 173 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2602_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2602_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
